Gene-level copy-number profile of tumor specimen CUPP-B4JG-TTM1-A from CCG case CUPP-B4JG, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage IV; Age at diagnosis: 53.2 years (19,446 days).
Specimen CUPP-B4JG-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d8d4b9ef-591d-4c2c-b9c9-5d8339f40758.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B4JG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/ebd881b9-0200-4c15-8406-d1c3e9a730b0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 2,865; copy number 2: 56,029; copy number 3: 8; copy number 4: 2.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:41,542,069–41,544,310, 1 gene (within-gene range 0–2): AL445933.1.
- chr9:61,190,003–61,453,030, 7 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr16:90,173,217–90,222,851, 2 genes (within-gene range 0–2): LINC02193, CICP25.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 11. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
